Somatic mutation profile of tumor specimen BA2423D (aliquot aq-BA2423D) from BEATAML1.0 case 2151, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,176 days).
Specimen BA2423D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3e02f9c-ea4f-40a1-9ac6-ffd15ceae4b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2395D (Solid Tissue Normal), aliquot aq-BA2395D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90a16a46-9eaa-462c-8ed2-ca1e4e8fefe9

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HHAT | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs148466987; called by mutect2, varscan2
- ASPN | c.712+1G>T p.X238_splice | Splice Site (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- RTEL1 | c.2248C>A p.R750S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- SLC24A4 | c.1854C>A p.C618* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- ZSWIM4 | c.661C>A p.R221S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
